Somatic mutation profile of tumor specimen TCGA-YZ-A984-01A (aliquot TCGA-YZ-A984-01A-11D-A39W-08) from TCGA case TCGA-YZ-A984, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.2 years (18,342 days).
Specimen TCGA-YZ-A984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a60d688c-09af-4597-ba89-f09d7cbf05b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YZ-A984-10A (Blood Derived Normal), aliquot TCGA-YZ-A984-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26da0383-9849-44d3-8636-b837cf1902e7

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC40 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as rs1409140018, COSV57011845; called by muse, mutect2, varscan2
- CHML | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs200203736; called by muse, mutect2, varscan2
- SIGLEC1 | c.3325G>A p.V1109M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748962316; called by muse, mutect2, varscan2
- BAP1 | c.1262del p.K421Rfs*9 | Frame Shift Del (DEL) | VAF 33/54 reads (61%) | called by mutect2, pindel, varscan2
- CYLD | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2
- HERC2 | c.8089G>T p.E2697* | Nonsense Mutation (SNP) | VAF 63/118 reads (53%) | called by muse, mutect2, varscan2
- TMEM44 | c.348G>A p.K116= | Silent (SNP) | VAF 55/66 reads (83%) | catalogued as rs1297791553; called by muse, mutect2, varscan2
